Gene-level copy-number profile of tumor specimen HCM-CSHL-0818-C56-06A from HCMI case HCM-CSHL-0818-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,709 days).
Specimen HCM-CSHL-0818-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 987b265a-614d-4e00-8d35-d7bc40b3e93b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0818-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/471483f0-ed95-4dd6-9ecf-66068626122d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 137; copy number 1: 4,311; copy number 2: 19,855; copy number 3: 19,240; copy number 4: 7,981; copy number 5: 5,353; copy number 6: 963; copy number 7: 157; copy number 8: 61; copy number 9: 101; copy number 10: 233.

Homozygous deletions (total copy number 0; autosomes only): 137 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,492,300–2,591,469, 10 genes (within-gene range 0–1): AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B.
- chr5:88,189,633–94,618,122, 71 genes (within-gene range 0–1) (broad region; genes not listed).
- chr15:30,083,053–30,759,859, 42 genes: GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2, ARHGAP11B, AC091057.5, Y_RNA, AC091057.4.
- chr17:31,090,787–31,538,211, 14 genes (within-gene range 0–1): AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 552 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,534,449–39,790,171, 72 genes, copy number 10 (broad region; genes not listed).
- chr1:42,903,232–43,323,108, 15 genes, copy number 10: ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, AL161637.1, FAM183A, EBNA1BP2, MIR6733, CFAP57, RNA5SP46, TMEM125, C1orf210, TIE1.
- chr1:43,358,981–43,389,808, 5 genes, copy number 10: CDC20, ELOVL1, MIR6734, MED8, MED8-AS1.
- chr1:43,991,500–46,221,256, 84 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr1:58,933,643–59,240,555, 1 gene, copy number 9 (within-gene range 5–9): LINC01358.
- chr1:59,131,932–62,710,694, 40 genes, copy number 9: HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1.
- chr3:196,527,339–198,123,232, 54 genes, copy number 7: AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr8:91,542,924–92,683,450, 12 genes, copy number 7: AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1.
- chr8:99,873,200–102,412,759, 67 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:104,489,231–106,770,244, 24 genes, copy number 7–8: LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA.
- chr8:135,742,343–139,704,109, 16 genes, copy number 7: RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr9:61,190,003–61,453,030, 7 genes, copy number 7: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr18:9,020,029–9,020,764, 1 gene, copy number 8: RPS4XP19.
- chr18:21,825,487–21,831,539, 3 genes, copy number 8 (within-gene range 5–8): MIR133A1HG, MIR133A1, MIR1-2.
- chr18:21,871,446–26,099,226, 77 genes, copy number 8–10 (broad region; genes not listed).
- chr19:27,638,483–29,525,752, 41 genes, copy number 7–8 (within-gene range 6–8): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1.
- chr19:43,785,874–44,367,217, 33 genes, copy number 7 (within-gene range 5–7): LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112.

Autosomal genes at a single copy (total copy number 1): 4,311. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
